Somatic mutation profile of tumor specimen TCGA-D5-6930-01A (aliquot TCGA-D5-6930-01A-11D-1924-10) from TCGA case TCGA-D5-6930, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIA; Age at diagnosis: 67.8 years (24,764 days).
Specimen TCGA-D5-6930-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe240d3e-2ff4-4bcc-983d-acee16e049d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D5-6930-10A (Blood Derived Normal), aliquot TCGA-D5-6930-10A-01D-1924-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55c6eb69-d3d7-4464-86a0-7165622ab4ce

The open-access MAF lists 1,451 somatic variants for this specimen: 1,086 protein-altering or splice-affecting, 343 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 768, Silent 343, Frame Shift Del 191, Nonsense Mutation 62, Frame Shift Ins 42, Splice Region 10, Intron 9, RNA 7, In Frame Del 6, Splice Site 6, 3'UTR 2, 5'UTR 2.

Variants (750 of 1,451; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AXIN2 | c.1994del p.G665Afs*24 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | catalogued as rs267606674; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CRB1 | c.1783G>A p.A595T | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.052); catalogued as rs752212470, COSV66331230; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KMT2A | c.2318del p.P773Rfs*8 | Frame Shift Del (DEL) | VAF 42/233 reads (18%) | catalogued as rs782297546; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- LSM14A | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 17/128 reads (13%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as COSV70884731; called by muse, mutect2, varscan2
- MCCC2 | c.1081C>T p.R361* | Nonsense Mutation (SNP) | VAF 15/99 reads (15%) | catalogued as rs763293192, COSV60157117; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH2 | c.2131C>T p.R711* | Nonsense Mutation (SNP) | VAF 18/59 reads (31%) | catalogued as rs63750636, CM011424, COSV51877754; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.3227G>A p.R1076H | Missense Mutation (SNP) | VAF 27/202 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs779617676, CM144063, COSV52274821; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 14/88 reads (16%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- MYL3 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.826); catalogued as rs104893749, CM961008, COSV52768329; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- NONO | c.1093C>T p.R365* | Nonsense Mutation (SNP) | VAF 10/65 reads (15%) | catalogued as rs869025345, CM1512177, COSV52137834; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RIN2 | c.1878del p.I627Sfs*4 (on ENST00000255006 / NM_001242581.1; = p.I578Sfs*4 on NM_018993.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 17/88 reads (19%) | catalogued as rs759390822; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RP1 | c.2700dup p.P901Tfs*2 | Frame Shift Ins (INS) | VAF 24/87 reads (28%) | catalogued as rs797044735; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- SERAC1 | c.442C>T p.R148* | Nonsense Mutation (SNP) | VAF 19/135 reads (14%) | catalogued as rs387907236, CM125509, COSV100894824, COSV100894917; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SF3B4 | c.1147del p.H383Mfs*75 | Frame Shift Del (DEL) | VAF 15/55 reads (27%) | catalogued as rs387907186, CD123383; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SLC17A5 | c.349del p.Y117Mfs*17 | Frame Shift Del (DEL) | VAF 29/130 reads (22%) | catalogued as rs772039085; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- TOP3A | c.2271del p.R758Gfs*15 | Frame Shift Del (DEL) | VAF 10/64 reads (16%) | catalogued as rs752838075; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- A2M | c.3720G>T p.K1240N | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59392934; called by muse, varscan2
- AADACL4 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.086); catalogued as rs139261871; called by muse, mutect2, varscan2
- AADACL4 | c.1076G>A p.R359H | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); catalogued as rs150325490; called by muse, mutect2, varscan2
- ABCB1 | c.1542G>A p.M514I | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV55964706; called by muse, mutect2, varscan2
- ABCD4 | c.556G>A p.G186R | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1410990711, COSV53994658; called by muse, mutect2, varscan2
- ABCE1 | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56849175; called by muse, mutect2, varscan2
- ACBD6 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62576437; called by muse, mutect2
- ACSF3 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as rs745453668, COSV58080583; called by muse, mutect2, varscan2
- ACSM3 | c.1645dup p.T549Nfs*29 | Frame Shift Ins (INS) | VAF 12/54 reads (22%) | catalogued as rs757021642; called by mutect2, varscan2
- ACTR10 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.095); catalogued as rs554639681, COSV54298006; called by muse, mutect2, varscan2
- ACTR5 | c.1747G>A p.A583T | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV54760449; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 43/82 reads (52%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM7 | c.655C>T p.H219Y | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.39); catalogued as COSV51535236; called by muse, mutect2, varscan2
- ADAM8 | c.1281del p.E428Rfs*32 | Frame Shift Del (DEL) | VAF 12/49 reads (24%) | catalogued as rs753471255, COSV69864363; called by mutect2, pindel, varscan2
- ADAMTS12 | c.1343G>A p.W448* | Nonsense Mutation (SNP) | VAF 14/62 reads (23%) | catalogued as COSV61281339; called by muse, mutect2, varscan2
- ADAMTS8 | c.1516C>A p.L506I | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.065); catalogued as COSV57298258; called by muse, mutect2, varscan2
- ADAMTS9 | c.3665del p.C1222Lfs*15 | Frame Shift Del (DEL) | VAF 20/78 reads (26%) | catalogued as COSV55791588; called by mutect2, pindel, varscan2
- ADAMTSL4 | c.526C>T p.R176W | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs751378344, COSV55007879; called by muse, mutect2, varscan2
- ADCY1 | c.2015G>A p.R672H | Missense Mutation (SNP) | VAF 34/159 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as rs201204048, COSV52030269; called by muse, mutect2, varscan2
- ADGRG3 | c.727G>A p.V243M | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as rs868457442, COSV59652870; called by muse, mutect2, varscan2
- ADGRL2 | c.3535C>T p.R1179* | Nonsense Mutation (SNP) | VAF 42/206 reads (20%) | catalogued as rs754660598, COSV99592101; called by muse, mutect2, varscan2
- ADRA1B | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60701808; called by muse, mutect2, varscan2
- AFAP1L2 | c.1543G>A p.V515M | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.215); catalogued as COSV100413225; called by muse, mutect2
- AFF3 | c.277G>A p.V93I | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs753942953, COSV57867140, COSV57875200; called by muse, mutect2, varscan2
- AFG1L | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as COSV64558567; called by muse, mutect2, varscan2
- AGRN | c.4615G>T p.A1539S | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV65072562; called by muse, mutect2, varscan2
- AHNAK | c.1884G>A p.M628I | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.899); catalogued as rs770053221, COSV57232371; called by muse, mutect2, varscan2
- AJM1 | c.10A>G p.T4A | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV99915973; called by muse, varscan2
- AKAP4 | c.199G>T p.G67C | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.575); catalogued as COSV100654372, COSV62075579; called by muse, mutect2, varscan2
- AKAP9 | c.11307dup p.Q3770Afs*52 (on ENST00000359028; = p.Q3746Afs*52 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 8/48 reads (17%) | catalogued as rs747796926; called by mutect2, varscan2
- ALAS1 | c.1597C>T p.R533W | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs963162082, COSV59630094; called by muse, mutect2, varscan2
- ALDH9A1 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145012858; called by muse, mutect2, varscan2
- ALPG | c.822G>T p.Q274H | Missense Mutation (SNP) | VAF 17/167 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.612); catalogued as COSV54968393; called by muse, mutect2, varscan2
- ALPK3 | c.3154C>G p.R1052G | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV51928873, COSV99362190; called by mutect2, varscan2
- AMPD2 | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV56651080; called by muse, mutect2, varscan2
- AMPD2 | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as rs747822677, COSV56647234; called by muse, mutect2, varscan2
- AMPD2 | c.1474C>T p.R492C | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.868); catalogued as rs1333072178, COSV56651107; called by muse, varscan2
- ANGPT4 | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.69); PolyPhen benign (0.011); catalogued as COSV67922627; called by muse, mutect2, varscan2
- ANK1 | c.2961-2A>C p.X987_splice | Splice Site (SNP) | VAF 11/75 reads (15%) | catalogued as COSV99227318; called by muse, mutect2, varscan2
- ANKS6 | c.1012C>T p.Q338* | Nonsense Mutation (SNP) | VAF 4/33 reads (12%) | catalogued as COSV100782416; called by muse, mutect2
- ANO6 | c.1192C>T p.R398* | Nonsense Mutation (SNP) | VAF 31/156 reads (20%) | catalogued as rs751953918, COSV57668573; called by muse, mutect2, varscan2
- ANXA8 | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1481860205; called by mutect2, varscan2
- AP2A2 | c.901C>T p.H301Y | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV59964365; called by muse, mutect2, varscan2
- ARAP1 | c.3338C>T p.T1113M (on ENST00000393609 / NM_001040118.2; = p.T868M on NM_015242.4) | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs754647744, COSV61995474; called by mutect2, varscan2
- ARFGEF2 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs778834589, COSV64211088; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGAP21 | c.5684A>C p.N1895T | Missense Mutation (SNP) | VAF 82/317 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100256828; called by muse, mutect2, varscan2
- ARHGAP31 | c.3751T>A p.S1251T | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.054); catalogued as COSV51799701; called by muse, mutect2, varscan2
- ARHGAP9 | c.661C>T p.Q221* | Nonsense Mutation (SNP) | VAF 27/139 reads (19%) | catalogued as COSV62724608; called by muse, mutect2, varscan2
- ARHGEF19 | c.2365C>T p.R789* | Nonsense Mutation (SNP) | VAF 15/50 reads (30%) | catalogued as rs746448541, COSV54617190; called by muse, mutect2, varscan2
- ARHGEF40 | c.3028G>T p.A1010S | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV53884698; called by muse, mutect2, varscan2
- ARHGEF5 | c.3692C>T p.T1231M | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.085); catalogued as rs764474357; called by mutect2, varscan2
- ARID1B | c.1694G>A p.R565Q | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs754042537, COSV51657362; called by muse, mutect2, varscan2
- ARL14 | c.355G>A p.V119I | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.044); catalogued as COSV57900543; called by muse, mutect2, varscan2
- ASB2 | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV60110211; called by muse, varscan2
- ASB2 | c.1175A>T p.D392V | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1397987654, COSV60114680; called by muse, varscan2
- ASB2 | c.1067C>T p.A356V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as COSV100279687; called by muse, varscan2
- ASPA | c.387G>T p.E129D | Missense Mutation (SNP) | VAF 62/241 reads (26%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.877); catalogued as COSV99559357; called by muse, mutect2, varscan2
- ASPDH | c.785C>T p.T262M (on ENST00000389208 / NM_001114598.2; = p.T157M on NM_001024656.3) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.765); catalogued as COSV65350402; called by muse, mutect2
- ASPSCR1 | c.1367C>T p.P456L | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764426390, COSV60716293, COSV60716527; called by muse, mutect2, varscan2
- ASTE1 | c.1066C>T p.Q356* | Nonsense Mutation (SNP) | VAF 30/111 reads (27%) | catalogued as rs766304746, COSV53910778; called by muse, mutect2, varscan2
- ATAD2B | c.1861G>A p.A621T | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs376297258, COSV53195015; called by muse, mutect2, varscan2
- ATG2A | c.3596G>T p.S1199I | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.896); catalogued as COSV65968999; called by muse, mutect2, varscan2
- ATG9B | c.1937G>A p.R646H | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.473); catalogued as rs1175239634, COSV52496289; called by muse, mutect2
- ATP10A | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs147157402, COSV63513255; called by muse, mutect2, varscan2
- ATP1A1 | c.1528G>A p.A510T | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55191098; called by muse, mutect2, varscan2
- ATP2C1 | c.1948G>A p.V650I | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.836); catalogued as COSV100147065; called by muse, mutect2, varscan2
- ATP8A2 | c.3177A>C p.R1059S | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV99684947; called by muse, mutect2, varscan2
- ATP8B1 | c.2258C>T p.T753I | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.24); catalogued as rs748391460, COSV52180628; called by muse, mutect2, varscan2
- ATP8B2 | c.146C>T p.A49V (on ENST00000672630; = p.A16V on NM_001005855.2) | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368910102; called by muse, mutect2, varscan2
- ATP8B2 | c.536C>T p.A179V (on ENST00000672630; = p.A146V on NM_001005855.2) | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.244); catalogued as rs776939812, COSV59245184; called by muse, mutect2, varscan2
- ATP8B2 | c.1505G>A p.R502H (on ENST00000672630; = p.R469H on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs756550470, COSV59249270; called by mutect2, varscan2
- ATXN7L3 | c.674G>A p.R225H (on ENST00000389384 / NM_001382309.1; = p.R232H on NM_001382308.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.132); catalogued as COSV60228759; called by muse, mutect2, varscan2
- AXL | c.874del p.H292Ifs*5 | Frame Shift Del (DEL) | VAF 20/94 reads (21%) | catalogued as rs778012871; called by mutect2, pindel, varscan2
- BAIAP3 | c.1469C>T p.A490V | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.092); catalogued as COSV60984386; called by muse, mutect2, varscan2
- BANP | c.1457C>T p.A486V (on ENST00000286122; = p.A436V on NM_017869.4) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); catalogued as rs867560277, COSV53743423; called by muse, mutect2, varscan2
- BARHL1 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55037165, COSV55039029; called by muse, mutect2, varscan2
- BARX1 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.861); catalogued as COSV54159260; called by muse, mutect2, varscan2
- BCL11A | c.2020G>T p.G674* (on ENST00000335712 / NM_001365609.1; = p.G708* on NM_018014.4) | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as COSV59629118, COSV59637864; called by muse, mutect2, varscan2
- BCR | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.513); catalogued as rs1220313294, COSV59936145; called by muse, mutect2, varscan2
- BICC1 | c.2603A>T p.N868I | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as COSV54067262; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 41/98 reads (42%) | catalogued as rs772920507, COSV65808737; called by mutect2, varscan2
- BMPR2 | c.2618G>A p.R873Q | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.205); catalogued as rs201781338, CM085277, COSV65813690; ClinVar: likely benign; called by muse, mutect2, varscan2
- BRCA2 | c.2296G>A p.A766T | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV66463177; called by muse, mutect2, varscan2
- BRD3 | c.1117G>A p.A373T | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.935); catalogued as rs775918544, COSV57701452; called by muse, mutect2, varscan2
- BRD3 | c.458A>G p.K153R | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV57706941; called by muse, mutect2, varscan2
- BRINP1 | c.2008C>T p.R670C | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs1341594254, COSV56314239; called by muse, mutect2, varscan2
- BTG3 | c.685A>G p.T229A | Missense Mutation (SNP) | VAF 39/186 reads (21%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.636); catalogued as COSV100336411; called by muse, mutect2, varscan2
- BUB1 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as rs143906507; called by muse, mutect2, varscan2
- BUB3 | c.405_406del p.Q136Afs*2 | Frame Shift Del (DEL) | VAF 21/109 reads (19%) | catalogued as rs1296234927; called by pindel, varscan2
- C19orf44 | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs1282625596, COSV99685399; called by muse, mutect2, varscan2
- C1orf127 | c.1877G>A p.R626H | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs748761694, COSV65438750, COSV65439148; called by muse, varscan2
- C5orf24 | c.152T>C p.M51T | Missense Mutation (SNP) | VAF 46/222 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as rs1256922007, COSV100574608; called by muse, mutect2, varscan2
- CA9 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.095); catalogued as rs1563923684, COSV61407870; called by muse, mutect2, varscan2
- CABP2 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs758423379, COSV53709927; called by mutect2, varscan2
- CACNA1E | c.4940G>A p.R1647Q | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.364); catalogued as rs1317486763, COSV62429468; called by muse, mutect2, varscan2
- CACNA1G | c.6948del p.E2317Rfs*47 | Frame Shift Del (DEL) | VAF 15/79 reads (19%) | catalogued as rs766047428; called by mutect2, pindel, varscan2
- CACNA1S | c.4037del p.P1346Qfs*78 | Frame Shift Del (DEL) | VAF 25/112 reads (22%) | catalogued as COSV100755361, COSV100755470; called by mutect2, varscan2
- CACNA2D1 | c.2597A>T p.D866V (on ENST00000356253 / NM_001366867.1; = p.D854V on NM_000722.4) | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV62393789; called by muse, mutect2, varscan2
- CACNA2D1 | c.177T>G p.D59E | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62393795; called by muse, mutect2, varscan2
- CACNA2D4 | c.1216G>A p.G406S | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375148197, COSV54948000; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNG1 | c.367C>A p.L123I | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as CM1412812, COSV99871851; called by muse, mutect2, varscan2
- CAD | c.4387C>T p.R1463* | Nonsense Mutation (SNP) | VAF 29/101 reads (29%) | catalogued as COSV53031589; called by muse, mutect2, varscan2
- CAMK2A | c.1213C>T p.R405W (on ENST00000348628 / NM_171825.2; = p.R416W on NM_015981.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as rs1362570011, COSV62247933; called by muse, mutect2
- CAMSAP2 | c.2317C>T p.R773C (on ENST00000236925 / NM_001297707.2; = p.R762C on NM_203459.3) | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs775199276, COSV52669927; called by muse, mutect2, varscan2
- CAPRIN2 | c.2705del p.R902Kfs*19 | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | catalogued as COSV51835948; called by mutect2, pindel, varscan2
- CARD10 | c.1578del p.S527Vfs*31 | Frame Shift Del (DEL) | VAF 10/43 reads (23%) | catalogued as rs35832225; called by mutect2, pindel, varscan2
- CARD9 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs772249417, COSV53738140; called by muse, mutect2, varscan2
- CASKIN1 | c.2332del p.Q778Rfs*27 | Frame Shift Del (DEL) | VAF 21/104 reads (20%) | catalogued as rs1257000972; called by mutect2, pindel, varscan2
- CASZ1 | c.2951C>T p.A984V | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs569836726, COSV59741491; called by muse, mutect2, varscan2
- CATIP | c.23C>T p.T8I | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV56824554; called by muse, mutect2, varscan2
- CBLIF | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 60/221 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV57240549; called by muse, mutect2, varscan2
- CC2D1A | c.1169G>A p.R390Q | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as rs759926288, COSV58782538; called by muse, varscan2
- CCDC15 | c.581del p.K194Rfs*29 | Frame Shift Del (DEL) | VAF 26/106 reads (25%) | catalogued as rs759789184, COSV99049086; called by mutect2, varscan2
- CCDC170 | c.1914dup p.S639Ifs*34 | Frame Shift Ins (INS) | VAF 26/130 reads (20%) | catalogued as rs751612825; called by mutect2, varscan2
- CCDC174 | c.908del p.K303Rfs*2 | Frame Shift Del (DEL) | VAF 101/425 reads (24%) | catalogued as rs1229700711; called by mutect2, pindel, varscan2
- CCDC50 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 83/312 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776014358, COSV66667353; called by muse, mutect2, varscan2
- CCDC61 | c.1519C>T p.R507* | Nonsense Mutation (SNP) | VAF 19/63 reads (30%) | catalogued as rs200262706, COSV50517675; called by muse, mutect2, varscan2
- CCDC8 | c.926C>A p.A309D | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as COSV100282211; called by muse, mutect2, varscan2
- CCDC97 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.041); catalogued as rs1286685402, COSV54189870; called by muse, mutect2, varscan2
- CCDC97 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs752646666, COSV54189651; called by muse, mutect2, varscan2
- CCND3 | c.731A>G p.Q244R | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100027006; called by mutect2, varscan2
- CD163 | c.3070G>A p.A1024T | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs145413017; called by muse, mutect2, varscan2
- CD5L | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.163); catalogued as COSV63823264; called by muse, mutect2, varscan2
- CDC73 | c.750dup p.A251Cfs*16 | Frame Shift Ins (INS) | VAF 42/267 reads (16%) | catalogued as COSV100813688; called by mutect2, pindel, varscan2
- CDCA4 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs372232233; called by muse, mutect2, varscan2
- CDH15 | c.1162del p.A388Hfs*89 | Frame Shift Del (DEL) | VAF 7/22 reads (32%) | catalogued as COSV99228980; called by mutect2, varscan2
- CDH18 | c.1792C>T p.R598W | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.821); catalogued as rs755435892, COSV56915596; called by muse, mutect2, varscan2
- CDHR3 | c.2135T>C p.V712A | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58422283; called by muse, mutect2, varscan2
- CDK10 | c.190A>G p.I64V | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.086); catalogued as COSV58416445; called by muse, mutect2, varscan2
- CDK5RAP2 | c.2255C>T p.T752M | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs202244167; called by muse, mutect2
- CELSR2 | c.5753G>A p.S1918N | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.057); catalogued as rs1557734144, COSV54780012; called by muse, mutect2, varscan2
- CELSR2 | c.6151C>T p.R2051C | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as rs757707208, COSV54780019; called by muse, mutect2, varscan2
- CENPQ | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 44/355 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0.006); catalogued as COSV100225903; called by muse, mutect2, varscan2
- CEP126 | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 42/158 reads (27%) | catalogued as rs374091656; called by muse, mutect2, varscan2
- CEP170B | c.3187G>A p.A1063T (on ENST00000453495; = p.A992T on NM_015005.3) | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as COSV69026767; called by muse, varscan2
- CFAP251 | c.3025G>A p.E1009K | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs776727712, COSV56608786; called by muse, varscan2
- CFAP46 | c.5782C>T p.R1928W | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs762437213, COSV54160036; called by muse, mutect2, varscan2
- CFAP58 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.065); catalogued as rs200132388, COSV57212082, COSV57213757; called by mutect2, varscan2
- CGN | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs1045284968, COSV54967957, COSV99641820; called by muse, mutect2
- CGN | c.2305C>T p.R769W | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1205017142, COSV54974016; called by muse, mutect2, varscan2
- CHGB | c.1886C>A p.P629Q | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.92); PolyPhen benign (0.01); catalogued as rs1229523720, COSV66761891; called by muse, mutect2
- CHRD | c.1879G>A p.A627T | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763717398, COSV52612844; called by muse, mutect2, varscan2
- CHST3 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64151842; called by muse, mutect2
- CHST4 | c.19del p.M7* | Frame Shift Del (DEL) | VAF 7/24 reads (29%) | catalogued as rs745406065; called by mutect2, varscan2
- CKAP2 | c.1817del p.K606Rfs*14 (on ENST00000378037 / NM_001098525.2; = p.K605Rfs*14 on NM_018204.5) | Frame Shift Del (DEL) | VAF 9/49 reads (18%) | catalogued as rs752250702; called by mutect2, varscan2
- CLCN2 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1331258576, COSV55604609; called by muse, mutect2, varscan2
- CLDN16 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs762831659, COSV53227188; called by mutect2, varscan2
- CLEC10A | c.571A>C p.S191R (on ENST00000254868 / NM_182906.4; = p.S167R on NM_006344.4) | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV99645013; called by muse, mutect2, varscan2
- CLEC12A | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58562779; called by muse, mutect2, varscan2
- CLEC14A | c.1442C>T p.A481V | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); catalogued as rs1236628033, COSV60561689; called by muse, mutect2, varscan2
- CLEC14A | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as rs11553024, COSV60562671; called by muse, varscan2
- CLEC4A | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.457); catalogued as COSV57562993, COSV99983633; called by muse, mutect2, varscan2
- CLSTN1 | c.1606C>T p.R536* (on ENST00000377298 / NM_001009566.3; = p.R526* on NM_014944.4) | Nonsense Mutation (SNP) | VAF 13/49 reads (27%) | catalogued as rs1477902252, COSV63648364; called by muse, mutect2, varscan2
- CMIP | c.844C>T p.R282* (on ENST00000537098 / NM_198390.2; = p.R188* on NM_030629.3) | Nonsense Mutation (SNP) | VAF 7/30 reads (23%) | catalogued as rs1180904276, COSV67697948; called by muse, mutect2, varscan2
- CMIP | c.1114C>T p.R372C (on ENST00000537098 / NM_198390.2; = p.R278C on NM_030629.3) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs1024601643, COSV101220977; called by muse, mutect2, varscan2
- CMTM3 | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0.027); catalogued as rs372483559; called by muse, mutect2, varscan2
- CNNM2 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.353); catalogued as COSV63996499; called by muse, mutect2
- CNP | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs960647116, COSV66369289; called by muse, mutect2, varscan2
- CNTN6 | c.2231G>A p.G744D | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100611560, COSV63191186; called by muse, mutect2, varscan2
- CNTNAP5 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.709); catalogued as rs201163242, COSV70513494; called by muse, mutect2, varscan2
- COA7 | c.344G>A p.G115D | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV65299992; called by muse, mutect2, varscan2
- COASY | c.1025G>A p.G342E | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55900561; called by muse, mutect2
- COBL | c.1562C>T p.A521V | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1374552845, COSV54359838; called by muse, mutect2, varscan2
- COL11A1 | c.1635del p.P546Lfs*87 | Frame Shift Del (DEL) | VAF 45/371 reads (12%) | catalogued as COSV100615079, COSV62186140; called by mutect2, pindel, varscan2
- COL12A1 | c.7171C>A p.L2391I | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.988); catalogued as COSV59409182; called by muse, mutect2
- COL14A1 | c.2728G>A p.A910T | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs781191822, COSV52848407; called by muse, mutect2, varscan2
- COL18A1 | c.484del p.Q162Rfs*107 (on ENST00000359759 / NM_130444.3; = p.Q162Rfs*142 on NM_030582.4) | Frame Shift Del (DEL) | VAF 7/26 reads (27%) | catalogued as rs766977257; called by mutect2, varscan2
- COL4A2 | c.313G>A p.V105M | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); catalogued as rs772439696, COSV64625942; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A2 | c.1719T>G p.G573= | Splice Region (SNP) | VAF 13/56 reads (23%) | catalogued as COSV66415797; called by muse, mutect2, varscan2
- COMP | c.1153G>A p.D385N | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM030027, CM120445, COSV99721640; called by muse, mutect2, varscan2
- CORO7 | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs200117600, COSV99228160, COSV99228274; called by muse, mutect2, varscan2
- COX8A | c.114+2T>C p.X38_splice | Splice Site (SNP) | VAF 6/46 reads (13%) | catalogued as COSV100029309; called by mutect2, varscan2
- CPED1 | c.2579G>A p.G860D | Missense Mutation (SNP) | VAF 56/285 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60013872; called by muse, mutect2, varscan2
- CPQ | c.479A>G p.Q160R | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as COSV99615627; called by muse, mutect2
- CPS1 | c.3002G>A p.R1001H | Missense Mutation (SNP) | VAF 44/192 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs545355868, COSV51825670; called by muse, mutect2, varscan2
- CPT1A | c.693C>T p.Y231= | Splice Region (SNP) | VAF 10/36 reads (28%) | catalogued as rs146551320, COSV55754285; ClinVar: likely benign; called by mutect2, varscan2
- CPXCR1 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs754987127, COSV52164660; called by muse, mutect2, varscan2
- CROCC | c.1997G>T p.R666I | Missense Mutation (SNP) | VAF 28/238 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as rs777660553, COSV65015094; called by muse, mutect2, varscan2
- CRTC1 | c.1343G>A p.R448H | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs748706628, COSV58723883; called by muse, mutect2, varscan2
- CRYBG3 | c.7502A>T p.D2501V | Missense Mutation (SNP) | VAF 51/269 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV99477691; called by muse, mutect2, varscan2
- CSMD2 | c.3980G>A p.R1327H | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs772219815, COSV53884902; called by muse, mutect2, varscan2
- CSMD3 | c.10672C>T p.L3558F (on ENST00000297405 / NM_001363185.1; = p.L3389F on NM_052900.3) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV52131699, COSV52175526, COSV99847705; called by mutect2, varscan2
- CST1 | c.241del p.V81* | Frame Shift Del (DEL) | VAF 15/115 reads (13%) | catalogued as rs756924682; called by mutect2, pindel, varscan2
- CTH | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61009937; called by muse, mutect2, varscan2
- CTIF | c.245dup p.Q83Tfs*78 | Frame Shift Ins (INS) | VAF 9/36 reads (25%) | catalogued as rs779060416; called by mutect2, varscan2
- CTNNA2 | c.878C>T p.T293M | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV100783680, COSV63593723; called by muse, mutect2, varscan2
- CTU2 | c.486C>A p.C162* | Nonsense Mutation (SNP) | VAF 19/119 reads (16%) | catalogued as COSV56344165; called by muse, mutect2, varscan2
- CUL3 | c.2212C>T p.P738S | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as COSV52371134; called by muse, mutect2, varscan2
- CUL7 | c.4491G>A p.M1497I | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1326480470, COSV99539436; called by muse, mutect2
- CUL9 | c.2293C>T p.R765W | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs755755698, COSV52725573; called by muse, mutect2, varscan2
- CYP2A13 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs370968595, COSV57840310; called by muse, mutect2, varscan2
- DAP3 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as rs149919712; called by muse, varscan2
- DBF4B | c.1502C>T p.P501L | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs765334573, COSV59259346; called by muse, mutect2, varscan2
- DCC | c.2624C>T p.T875M | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as rs747051148, COSV59139035; called by muse, mutect2, varscan2
- DDX47 | c.1231C>T p.R411* | Nonsense Mutation (SNP) | VAF 19/79 reads (24%) | catalogued as rs201442242, COSV61912157; called by muse, mutect2, varscan2
- DENND5B | c.3266C>T p.A1089V | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV60908886; called by muse, mutect2, varscan2
- DGKI | c.984G>T p.K328N | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.277); catalogued as COSV55969998, COSV99937984; called by muse, mutect2
- DHX30 | c.2707G>A p.V903I (on ENST00000445061 / NM_138615.3; = p.V864I on NM_014966.3) | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.167); catalogued as COSV53143219; called by muse, mutect2, varscan2
- DIP2C | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 43/206 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as rs374564779, COSV55173768; called by muse, mutect2, varscan2
- DIS3L | c.2039C>T p.T680I (on ENST00000319212 / NM_001143688.3; = p.T597I on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); catalogued as COSV59914614; called by muse, mutect2, varscan2
- DKK2 | c.58G>C p.V20L | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV53404011; called by muse, mutect2, varscan2
- DKK4 | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs770888126, COSV55183557; called by muse, mutect2, varscan2
- DLEC1 | c.4775C>A p.P1592H | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57181130; called by muse, mutect2, varscan2
- DLX5 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56034475; called by muse, mutect2, varscan2
- DMPK | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.164); catalogued as rs376004763; called by muse, mutect2, varscan2
- DNAH1 | c.7198C>T p.P2400S | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs765237376, COSV70236958; called by muse, mutect2, varscan2
- DNAH10 | c.1086A>G p.I362M (on ENST00000409039; = p.I301M on NM_207437.3) | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.121); catalogued as COSV69003024; called by muse, mutect2, varscan2
- DNAH11 | c.3167G>A p.G1056D | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV60967625; called by muse, mutect2, varscan2
- DNAH7 | c.9762G>A p.R3254= | Splice Region (SNP) | VAF 14/178 reads (8%) | catalogued as COSV100418206; called by muse, mutect2
- DNAJC5B | c.460T>A p.S154T | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.621); catalogued as COSV52540597; called by muse, mutect2, varscan2
- DNHD1 | c.13670G>A p.R4557H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.044); catalogued as COSV54443881; called by muse, mutect2
- DNMT3A | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.059); catalogued as COSV53080271; called by muse, mutect2, varscan2
- DNMT3A | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV53037374, COSV99258021; called by muse, mutect2, varscan2
- DOC2A | c.153G>T p.E51D | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as rs763231450, COSV58752967; called by muse, mutect2, varscan2
- DOCK11 | c.2827G>T p.A943S | Missense Mutation (SNP) | VAF 66/141 reads (47%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as COSV52248294; called by muse, mutect2, varscan2
- DOCK3 | c.3373G>A p.E1125K | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV99816001; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 15/102 reads (15%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DPEP2 | c.1042A>T p.I348F | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.477); catalogued as COSV52056225; called by muse, mutect2, varscan2
- DRC3 | c.1493G>A p.R498H | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs756240634, COSV58266864; called by muse, mutect2, varscan2
- DRC7 | c.1479C>G p.N493K | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.853); catalogued as COSV61058018; called by muse, mutect2, varscan2
- DSCAM | c.1889G>A p.W630* | Nonsense Mutation (SNP) | VAF 12/81 reads (15%) | catalogued as COSV68025179; called by muse, mutect2, varscan2
- DSEL | c.2018A>C p.Q673P | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV59495203; called by muse, mutect2, varscan2
- DST | c.20702C>T p.A6901V (on ENST00000361203 / NM_001374722.1; = p.A4598V on NM_015548.5) | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs376556021; called by muse, mutect2, varscan2
- DUOX2 | c.4128A>T p.K1376N | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV66534990; called by muse, mutect2, varscan2
- DUSP9 | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV61438523; called by muse, mutect2, varscan2
- E2F7 | c.2600G>A p.R867H | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1249849684, COSV59741803; called by muse, mutect2, varscan2
- E2F7 | c.1080A>C p.K360N | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59743906; called by muse, mutect2, varscan2
- ECI2 | c.778G>A p.V260M (on ENST00000380118 / NM_206836.3; = p.V230M on NM_006117.2) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs41302847, COSV60990567; called by muse, mutect2, varscan2
- EEF2 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.89); catalogued as rs767351133, COSV58579938; called by muse, mutect2, varscan2
- EFL1 | c.3188A>C p.D1063A | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99189243; called by muse, mutect2
- EIF4G1 | c.536C>T p.T179M | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.609); catalogued as rs981309467, COSV59994460; called by muse, mutect2, varscan2
- EIF4G1 | c.2677C>T p.R893W (on ENST00000346169 / NM_198241.3; = p.R698W on NM_004953.5) | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs940435791, COSV59994470; called by muse, mutect2
- EML2 | c.880G>T p.D294Y | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV55604529; called by muse, mutect2, varscan2
- EMX1 | c.794G>A p.G265D | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50690353; called by muse, mutect2, varscan2
- ENTR1 | c.692C>T p.A231V (on ENST00000357365 / NM_001039707.2; = p.A208V on NM_006643.4) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.176); catalogued as rs1471950980, COSV53743041; called by muse, mutect2
- EOMES | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.007); catalogued as COSV99842432; called by muse, mutect2
- EPB41L3 | c.3112C>T p.R1038* | Nonsense Mutation (SNP) | VAF 16/69 reads (23%) | catalogued as COSV59443182; called by muse, mutect2, varscan2
- EPHA3 | c.1153C>T p.R385* | Nonsense Mutation (SNP) | VAF 19/103 reads (18%) | catalogued as COSV60706249; called by muse, mutect2, varscan2
- EPHA7 | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs770806616, COSV65170662; called by muse, mutect2, varscan2
- EPHB3 | c.1435C>T p.P479S | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.945); catalogued as rs564635010, COSV57809516; called by muse, mutect2, varscan2
- ETV3L | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs893426995, COSV71901217; called by muse, mutect2, varscan2
- ETV5 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs138683352; called by muse, mutect2, varscan2
- EXOC3L2 | c.1556C>T p.A519V | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV52974841; called by muse, mutect2, varscan2
- EXOSC1 | c.289A>G p.N97D | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100900676; called by muse, mutect2
- F8 | c.3538G>A p.V1180I | Missense Mutation (SNP) | VAF 59/119 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs782113486, COSV64279172; called by muse, mutect2, varscan2
- FAM120A | c.2432T>C p.L811P | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52911623; called by muse, mutect2, varscan2
- FAM126A | c.1340C>T p.A447V | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs777996428, COSV69472245; called by muse, mutect2, varscan2
- FAM136A | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.503); catalogued as rs748392606, COSV50683259; called by muse, mutect2, varscan2
- FAM168B | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.025); catalogued as rs1434770306, COSV66304881; called by muse, mutect2, varscan2
- FAM170A | c.902G>A p.G301E | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs770553476, COSV58927341; called by muse, mutect2, varscan2
- FAM214A | c.2170G>A p.E724K | Missense Mutation (SNP) | VAF 39/211 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as COSV99958648; called by muse, mutect2, varscan2
- FAM214B | c.293C>A p.T98N | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.062); catalogued as COSV59717698; called by muse, mutect2
- FAM222A | c.1234C>A p.L412I | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100734646; called by muse, mutect2, varscan2
- FAM222B | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.947); catalogued as rs770300215, COSV57934640; called by muse, mutect2, varscan2
- FAM47C | c.2251C>T p.R751C | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV63728177; called by muse, mutect2, varscan2
- FAM71E1 | c.685C>T p.R229W (on ENST00000600100 / NM_001308429.2; = p.R213W on NM_138411.3) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760610760, COSV63100296; called by muse, mutect2, varscan2
- FAM78B | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.482); catalogued as rs1344714719, COSV57979925; called by muse, mutect2, varscan2
- FAM81B | c.1141G>C p.E381Q | Missense Mutation (SNP) | VAF 67/320 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV51987221; called by muse, mutect2, varscan2
- FAM90A1 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV56715143; called by muse, mutect2
- FANCD2 | c.1030_1032del p.I344del | In Frame Del (DEL) | VAF 30/134 reads (22%) | catalogued as rs760361533; called by pindel, varscan2
- FAT1 | c.1597G>A p.V533I | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.89); PolyPhen benign (0.036); catalogued as rs757277027, COSV101499713; called by muse, mutect2, varscan2
- FAT4 | c.949C>T p.R317C | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs775610806, COSV101272512, COSV67894617; called by mutect2, varscan2
- FAT4 | c.10669del p.T3557Pfs*6 | Frame Shift Del (DEL) | VAF 21/109 reads (19%) | catalogued as COSV58710995; called by mutect2, pindel, varscan2
- FAXC | c.928C>T p.R310W | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as rs201322886, COSV67603973; called by muse, mutect2, varscan2
- FBRS | c.170G>A p.R57Q (on ENST00000287468; = p.R577Q on NM_001105079.3) | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs765666411, COSV54918968, COSV54919257; called by muse, mutect2, varscan2
- FBXO40 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as rs1431000491, COSV57528144; called by muse, mutect2, varscan2
- FBXW5 | c.1067G>A p.G356D | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56402743, COSV56404160; called by muse, mutect2, varscan2
- FCGR2A | c.743-1G>A p.X248_splice (on ENST00000271450 / NM_001136219.3; = p.X247_splice on NM_021642.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 37/297 reads (12%) | catalogued as COSV54840981; called by muse, mutect2, varscan2
- FLNA | c.4495G>A p.V1499M | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); catalogued as rs782701954, COSV100775409; called by muse, mutect2
- FLOT2 | c.945G>T p.E315D | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV101204818; called by muse, mutect2, varscan2
- FLT4 | c.1694C>T p.S565F | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV56118384, COSV56121481; called by muse, mutect2, varscan2
- FMO2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV52949071; called by muse, mutect2, varscan2
- FMR1NB | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 43/178 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.135); catalogued as rs782759389, COSV63272772; called by muse, mutect2, varscan2
- FNDC1 | c.3977G>A p.G1326D | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51944928, COSV51948408; called by muse, mutect2, varscan2
- FNDC1 | c.4237C>T p.R1413* | Nonsense Mutation (SNP) | VAF 24/82 reads (29%) | catalogued as rs767053118, COSV51948469; called by muse, mutect2, varscan2
- FNDC1 | c.5365C>T p.R1789C | Missense Mutation (SNP) | VAF 34/195 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760021818, COSV51948479; called by muse, mutect2, varscan2
- FNIP1 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.295); catalogued as COSV57201075; called by muse, mutect2, varscan2
- FOXB2 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV65024235; called by muse, mutect2, varscan2
- FOXL1 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV57215428; called by muse, mutect2, varscan2
- FRAS1 | c.11840C>T p.P3947L | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53602085; called by muse, mutect2, varscan2
- FRS3 | c.885G>A p.W295* | Nonsense Mutation (SNP) | VAF 28/110 reads (25%) | catalogued as COSV52487124; called by muse, mutect2, varscan2
- FSTL5 | c.689A>T p.D230V | Missense Mutation (SNP) | VAF 51/227 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60233132; called by muse, mutect2, varscan2
- FUT11 | c.755C>A p.A252E | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.97); PolyPhen benign (0.007); catalogued as COSV59545169; called by muse, mutect2, varscan2
- FZD2 | c.1091C>A p.A364D | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59530395; called by muse, mutect2, varscan2
- FZD2 | c.1231C>A p.P411T | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.103); catalogued as COSV59530404; called by muse, mutect2, varscan2
- GABBR2 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV52320789; called by muse, mutect2, varscan2
- GAD1 | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as rs765841229, COSV64026197; called by muse, mutect2, varscan2
- GALNT12 | c.447G>A p.W149* | Nonsense Mutation (SNP) | VAF 15/74 reads (20%) | catalogued as COSV100899169, COSV66663753; called by muse, mutect2, varscan2
- GAPVD1 | c.4418C>T p.T1473I (on ENST00000394104; = p.T1482I on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV52927883; called by muse, mutect2, varscan2
- GFPT1 | c.1978G>A p.D660N (on ENST00000357308 / NM_001244710.2; = p.D642N on NM_002056.4) | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61950989; called by muse, mutect2, varscan2
- GFPT2 | c.1768G>A p.V590I | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs538567339, COSV53812914; called by mutect2, varscan2
- GFRA1 | c.46C>T p.L16F | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100816323; called by muse, mutect2
- GFRA1 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100816325; called by muse, mutect2
- GIGYF1 | c.331del p.L111Wfs*234 | Frame Shift Del (DEL) | VAF 16/66 reads (24%) | catalogued as rs763147690; called by mutect2, varscan2
- GIMAP1 | c.583C>T p.R195W | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.148); catalogued as rs774081218, COSV56189956; called by mutect2, varscan2
- GIMAP4 | c.978C>A p.F326L | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.103); catalogued as COSV55434847, COSV99750387; called by muse, mutect2, varscan2
- GJB3 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs976148533, COSV64904436; called by muse, mutect2, varscan2
- GLG1 | c.2524G>A p.A842T | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV52667120; called by muse, mutect2, varscan2
- GLIS3 | c.745C>T p.Q249* | Nonsense Mutation (SNP) | VAF 5/14 reads (36%) | catalogued as COSV100175078; called by muse, mutect2, varscan2
- GLP2R | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV99302631; called by muse, mutect2
- GMPS | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 37/215 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV55812222; called by muse, mutect2, varscan2
- GNA15 | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); catalogued as COSV53588377; called by muse, mutect2, varscan2
- GNE | c.859G>A p.A287T (on ENST00000396594 / NM_001128227.3; = p.A256T on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.989); catalogued as rs375740268; called by muse, mutect2, varscan2
- GNPTAB | c.2989T>C p.Y997H | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV68449996; called by muse, mutect2, varscan2
- GOLGA2 | c.2929del p.Y977Tfs*9 | Frame Shift Del (DEL) | VAF 18/77 reads (23%) | catalogued as rs763679060; called by mutect2, varscan2
- GPC6 | c.386G>A p.G129D | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65539984; called by muse, mutect2, varscan2
- GPR141 | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.031); catalogued as rs369757172, COSV57732683; called by muse, mutect2, varscan2
- GPR158 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.084); catalogued as COSV66283744; called by muse, mutect2, varscan2
- GPR162 | c.686G>A p.G229E | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (1); PolyPhen possibly damaging (0.89); catalogued as rs782813287, COSV50592562; called by muse, mutect2, varscan2
- GPR17 | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.87); catalogued as rs575567390, COSV55757290; called by muse, varscan2
- GPR61 | c.757C>T p.R253W | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1465568054, COSV63984590; called by muse, mutect2, varscan2
- GPR68 | c.1039G>A p.A347T | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV99473324; called by muse, mutect2
- GPR89B | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 44/340 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs587629056, COSV100032685; called by mutect2, varscan2
- GPRASP1 | c.1498T>C p.S500P | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV64356569; called by muse, mutect2, varscan2
- GRAMD4 | c.1382C>T p.A461V | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.271); catalogued as rs1428712514, COSV100730588; called by muse, mutect2
- GREM2 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.536); catalogued as rs1044647734, COSV58947633; called by muse, mutect2, varscan2
- GRIK1 | c.2629C>A p.L877M | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.157); catalogued as rs867467071, COSV58733433; called by muse, mutect2, varscan2
- GRK5 | c.1034G>A p.R345Q | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1414195283, COSV64868025; called by muse, mutect2, varscan2
- GRK5 | c.1142G>A p.G381D | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64868031; called by muse, mutect2, varscan2
- GRM2 | c.2002G>A p.A668T | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.524); catalogued as rs1310863744, COSV56587721; called by muse, mutect2, varscan2
- GRM6 | c.2566C>T p.R856W | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs202022128, COSV51450081; called by muse, mutect2, varscan2
- GYS2 | c.1209del p.K403Nfs*7 | Frame Shift Del (DEL) | VAF 28/161 reads (17%) | catalogued as rs777954647, COSV53922451; called by mutect2, pindel, varscan2
- H1-5 | c.379G>A p.G127S | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV58899028; called by muse, mutect2, varscan2
- H1-6 | c.196C>T p.L66F | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs768594088, COSV58091547; called by muse, mutect2, varscan2
- H4C4 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.094); catalogued as rs573032310, COSV61591809; called by muse, mutect2, varscan2
- HAND1 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50563502; called by muse, mutect2, varscan2
- HAVCR1 | c.461C>T p.T154M | Missense Mutation (SNP) | VAF 69/281 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs201270450, COSV100208698; called by muse, mutect2, varscan2
- HCFC2 | c.167C>T p.T56M | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs756321771, COSV57560593; called by muse, mutect2, varscan2
- HCLS1 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV57528148; called by muse, mutect2, varscan2
- HDAC4 | c.898C>T p.P300S | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.178); catalogued as COSV61877185; called by muse, mutect2, varscan2
- HDDC2 | c.514G>T p.A172S | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.027); catalogued as COSV59533509; called by muse, mutect2, varscan2
- HDGF | c.149del p.F50Sfs*105 | Frame Shift Del (DEL) | VAF 10/59 reads (17%) | catalogued as COSV100625709; called by mutect2, varscan2
- HDLBP | c.3585G>T p.E1195D | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.598); catalogued as COSV51479788; called by muse, mutect2, varscan2
- HEATR5A | c.3134G>A p.C1045Y | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.796); catalogued as rs1373843216, COSV66346093; called by muse, mutect2, varscan2
- HECTD4 | c.12074A>G p.Y4025C | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.715); catalogued as COSV66392408; called by muse, mutect2, varscan2
- HELZ2 | c.1595G>T p.G532V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV100915747; called by muse, mutect2, varscan2
- HEPACAM2 | c.893G>A p.R298H (on ENST00000394468 / NM_001039372.4; = p.R286H on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as rs781506679, COSV59063725; called by muse, mutect2, varscan2
- HERC2 | c.10361C>T p.A3454V | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV55352214; called by muse, mutect2, varscan2
- HERC2 | c.6178G>A p.A2060T | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs558450056, COSV55309864, COSV55312927; called by muse, mutect2, varscan2
- HGF | c.330dup p.E111Rfs*5 | Frame Shift Ins (INS) | VAF 27/141 reads (19%) | catalogued as rs1186073562; called by mutect2, pindel, varscan2
- HIRA | c.2225C>T p.A742V | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.148); catalogued as rs774636516, COSV54280338; called by muse, mutect2, varscan2
- HLA-B | c.681C>A p.C227* | Nonsense Mutation (SNP) | VAF 32/164 reads (20%) | catalogued as COSV69520836; called by muse, varscan2
- HMCN1 | c.9696A>C p.K3232N | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.329); catalogued as COSV54944893; called by muse, mutect2, varscan2
- HMGN3 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1464435419, COSV99245746; called by muse, mutect2
- HOXA13 | c.676A>G p.K226E | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs763227546, COSV56084327; called by mutect2, varscan2
- HOXB4 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV60179055; called by muse, mutect2, varscan2
- HOXD1 | c.983C>T p.S328L | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.075); catalogued as rs867601012, COSV58923463; called by muse, mutect2, varscan2
- HR | c.1358C>T p.S453L | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs201564292, COSV57194898; called by muse, mutect2, varscan2
- HRC | c.61C>T p.L21F | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV53259121; called by muse, mutect2, varscan2
- HRH2 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV99200105; called by muse, mutect2, varscan2
- HSCB | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.213); catalogued as COSV53261930; called by muse, mutect2
- HSPG2 | c.6259C>T p.R2087* | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | catalogued as rs1196835948, COSV65971609; called by muse, mutect2, varscan2
- HTR2C | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs371347099, COSV52210409, COSV99348797; called by muse, mutect2, varscan2
- HTT | c.7238del p.P2413Hfs*44 | Frame Shift Del (DEL) | VAF 10/20 reads (50%) | catalogued as COSV100750826; called by mutect2, varscan2
- IARS2 | c.2657G>A p.R886Q | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV56960015; called by muse, mutect2, varscan2
- IDO1 | c.841C>T p.Q281* | Nonsense Mutation (SNP) | VAF 23/84 reads (27%) | catalogued as COSV53716499; called by muse, mutect2, varscan2
- IFNA2 | c.454T>C p.Y152H | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66506004; called by muse, mutect2, varscan2
- IFRD2 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201634662; called by muse, mutect2, varscan2
- IGF2BP1 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.344); catalogued as rs752711229, COSV51736512; called by muse, mutect2, varscan2
- IGF2R | c.3622G>A p.V1208M | Missense Mutation (SNP) | VAF 61/240 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs758491772, COSV63633134; called by muse, mutect2, varscan2
- IGKV3-11 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 61/193 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.08); catalogued as rs764467452; called by muse, mutect2, varscan2
- IKBIP | c.1009A>G p.K337E | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs1201051807, COSV61082833; called by muse, mutect2, varscan2
- IL17RB | c.1460C>T p.S487L | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.157); catalogued as rs1378339273, COSV51638714; called by muse, mutect2, varscan2
- IL1RL1 | c.710C>A p.A237D | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV99294653; called by muse, mutect2, varscan2
- ING4 | c.607C>T p.Q203* (on ENST00000396807 / NM_001127582.2; = p.Q202* on NM_016162.4) | Nonsense Mutation (SNP) | VAF 17/74 reads (23%) | catalogued as COSV57525516; called by muse, mutect2, varscan2
- INPP4B | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.022); catalogued as COSV53747354; called by muse, mutect2, varscan2
- INPP5E | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs779363781, COSV65496093; called by muse, mutect2, varscan2
- IPO8 | c.2434C>A p.P812T | Missense Mutation (SNP) | VAF 44/173 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.132); catalogued as COSV99805746; called by muse, mutect2, varscan2
- IQSEC1 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs754101583, COSV56229932; called by muse, mutect2, varscan2
- IQSEC2 | c.883C>T p.R295W (on ENST00000642864 / NM_001111125.3; = p.R90W on NM_015075.2) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV64728188; called by muse, mutect2
- IRX1 | c.1166G>A p.R389H | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57358038; called by muse, mutect2, varscan2
- ITGA1 | c.2003C>T p.A668V | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs1381525453, COSV50884928; called by muse, mutect2, varscan2
- ITGA2B | c.950C>T p.A317V | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752213788, COSV52234793; called by muse, mutect2, varscan2
- ITGA3 | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV50321404; called by muse, mutect2, varscan2
- ITGA5 | c.769C>T p.Q257* | Nonsense Mutation (SNP) | VAF 7/45 reads (16%) | catalogued as COSV99517033; called by muse, mutect2, varscan2
- ITGB4 | c.3368del p.P1123Lfs*37 | Frame Shift Del (DEL) | VAF 20/53 reads (38%) | catalogued as rs1441262033; called by mutect2, pindel, varscan2
- ITPRIPL1 | c.617G>A p.R206H (on ENST00000439118 / NM_001008949.3; = p.R214H on NM_178495.6) | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as rs150184854; called by muse, mutect2, varscan2
- ITSN1 | c.472dup p.L158Pfs*3 | Frame Shift Ins (INS) | VAF 26/106 reads (25%) | catalogued as rs751926247; called by mutect2, varscan2
- IWS1 | c.2128G>T p.E710* | Nonsense Mutation (SNP) | VAF 108/448 reads (24%) | catalogued as COSV54872138; called by muse, mutect2, varscan2
- JPH3 | c.1723C>T p.R575W | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs1403567656, COSV52468291; called by muse, varscan2
- KALRN | c.2917G>A p.D973N | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs746247182, COSV53761546; called by muse, mutect2, varscan2
- KAT7 | c.966G>T p.E322D | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as COSV52015318, COSV52017272; called by muse, mutect2, varscan2
- KCND2 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV58588617, COSV58606087, COSV58610421; called by muse, mutect2, varscan2
- KCNH7 | c.1715C>T p.A572V | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.31); catalogued as COSV59814989; called by muse, mutect2, varscan2
- KCNV2 | c.596G>A p.C199Y | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770865610, COSV66057617; called by muse, mutect2, varscan2
- KCNV2 | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1214477952, COSV66056449; called by muse, mutect2
- KCTD11 | c.739G>A p.G247S (on ENST00000333751 / NM_001363642.1; = p.G208S on NM_001002914.2) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as rs1337609841, COSV99342099; called by muse, mutect2
- KCTD8 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs905145774, COSV63598853; called by muse, mutect2
- KDM4A | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs769652752, COSV64960923; called by muse, mutect2, varscan2
- KDM4A | c.1699G>A p.A567T | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs190275733, COSV64959293; called by muse, mutect2, varscan2
- KDM4B | c.1474C>A p.P492T | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV50269582; called by muse, mutect2, varscan2
- KIAA1109 | c.3413G>A p.G1138D | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV52687182; called by muse, mutect2, varscan2
- KIAA1217 | c.643G>A p.V215I | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs574193479, COSV64613770; called by muse, mutect2, varscan2
- KIF13A | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775888626, COSV52447008, COSV52463401; called by muse, mutect2, varscan2
- KIF16B | c.1922G>A p.R641H | Missense Mutation (SNP) | VAF 56/201 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs747897403, COSV61715933; called by muse, mutect2, varscan2
- KIF1A | c.1722G>T p.E574D | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV100242747; called by muse, mutect2
- KIF1A | c.1231T>C p.S411P | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.059); catalogued as COSV100242751; called by muse, mutect2, varscan2
- KIF21B | c.3505G>A p.A1169T | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.018); catalogued as COSV59767469; called by muse, mutect2, varscan2
- KIF25 | c.1106G>A p.R369Q (on ENST00000354419 / NM_030615.2; = p.R317Q on NM_005355.3) | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as rs770647900, COSV63026301; called by muse, mutect2, varscan2
- KIF26A | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs199541796; called by mutect2, varscan2
- KIT | c.2195T>C p.V732A | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV55419546; called by muse, mutect2, varscan2
- KLB | c.2818C>T p.P940S | Missense Mutation (SNP) | VAF 51/204 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as COSV57300188, COSV57305479; called by muse, mutect2, varscan2
- KLF2 | c.818C>T p.T273I | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV50180063; called by muse, mutect2, varscan2
- KLHL30 | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as rs759593008, COSV59978809; called by mutect2, varscan2
- KRT4 | c.1297G>A p.D433N | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1214101230, COSV53409996; called by muse, mutect2, varscan2
- KRT40 | c.849G>T p.Q283H | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1279797482, COSV66697070, COSV66697164; called by muse, mutect2, varscan2
- KRTAP6-3 | c.278G>A p.G93D | Missense Mutation (SNP) | VAF 22/230 reads (10%) | PolyPhen probably damaging (0.989); catalogued as COSV101196523; called by muse, mutect2, varscan2
- LAMA1 | c.768C>T p.R256= | Splice Region (SNP) | VAF 13/51 reads (25%) | catalogued as rs774673002, COSV67542986; called by muse, mutect2, varscan2
- LAMC1 | c.2077C>T p.P693S | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV51182537; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 25/133 reads (19%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LCAT | c.1127G>T p.S376I | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99863388; called by muse, mutect2, varscan2
- LDLRAD4 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.021); catalogued as COSV63343533; called by muse, mutect2, varscan2
- LEPROTL1 | c.332C>A p.A111E | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.367); catalogued as COSV58305220; called by muse, mutect2, varscan2
- LGALS9 | c.1037del p.G346Afs*5 (on ENST00000395473 / NM_009587.3; = p.G314Afs*5 on NM_002308.4) | Frame Shift Del (DEL) | VAF 104/636 reads (16%) | catalogued as rs775745717; called by mutect2, pindel, varscan2
- LGR6 | c.644+1G>A p.X215_splice (on ENST00000367278 / NM_001017403.1; = p.X163_splice on NM_021636.3) | Splice Site (SNP) | VAF 16/62 reads (26%) | catalogued as COSV55167110; called by muse, mutect2, varscan2
- LHPP | c.312C>T p.D104= | Splice Region (SNP) | VAF 4/42 reads (10%) | catalogued as rs749562320, COSV64329064; called by mutect2, varscan2
- LIFR | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 57/278 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as rs757892555, COSV54689883; called by muse, mutect2, varscan2
- LINGO4 | c.1578dup p.L527Sfs*3 | Frame Shift Ins (INS) | VAF 18/78 reads (23%) | catalogued as rs893338622; called by mutect2, varscan2
- LMF2 | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as rs781069997, COSV53319340; called by muse, mutect2, varscan2
- LMO7 | c.4711T>C p.S1571P (on ENST00000357063; = p.S1252P on NM_005358.5) | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.198); catalogued as COSV100414009; called by muse, mutect2
- LOXL2 | c.1378T>G p.W460G | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66693782; called by muse, mutect2, varscan2
- LOXL3 | c.824del p.G275Afs*5 | Frame Shift Del (DEL) | VAF 32/62 reads (52%) | catalogued as rs746133895; called by mutect2, varscan2
- LRP2 | c.7256G>T p.R2419I | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.713); catalogued as COSV55563376; called by muse, mutect2, varscan2
- LRP2 | c.7093A>C p.T2365P | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.288); catalogued as COSV99790809; called by muse, mutect2, varscan2
- LRRC37A2 | c.3883T>C p.S1295P | Missense Mutation (SNP) | VAF 24/262 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.024); catalogued as rs1163239318, COSV61004519; called by muse, mutect2
- LRRC41 | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as rs1381211233, COSV100295679; called by muse, mutect2, varscan2
- LRRC71 | c.1440C>T p.I480= | Splice Region (SNP) | VAF 34/113 reads (30%) | catalogued as rs1198814939, COSV59359002; called by muse, mutect2, varscan2
- LRRN3 | c.113G>T p.R38M | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100074391; called by muse, mutect2, varscan2
- LTBP2 | c.1954C>A p.L652I | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.596); catalogued as COSV56214682; called by muse, mutect2, varscan2
- LY6K | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs1376238750, COSV52832393; called by muse, mutect2
- MAD1L1 | c.323C>T p.T108M | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.192); catalogued as rs200930173, COSV56248707; called by mutect2, varscan2
- MAGI1 | c.2944G>A p.G982S (on ENST00000402939 / NM_001033057.2; = p.G1010S on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV58346541; called by muse, mutect2
- MAP2K3 | c.695C>A p.A232D (on ENST00000342679 / NM_145109.3; = p.A203D on NM_002756.4) | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57571291, COSV57578541; called by muse, mutect2, varscan2
- MAP3K7CL | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as rs1157895552, COSV54512572; called by muse, mutect2, varscan2
- MAP7D2 | c.268C>T p.Q90* | Nonsense Mutation (SNP) | VAF 55/122 reads (45%) | catalogued as COSV65530618; called by muse, mutect2, varscan2
- MAP7D3 | c.1331C>T p.A444V | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.84); PolyPhen benign (0.161); catalogued as rs766563053, COSV60171117; called by muse, mutect2, varscan2
- MCM5 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1270174624, COSV53345656; called by muse, mutect2, varscan2
- MCTP1 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV72406850; called by muse, mutect2, varscan2
- MDC1 | c.2077G>T p.D693Y | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64528017; called by muse, mutect2, varscan2
- MECOM | c.709_711del p.R237del (on ENST00000468789 / NM_001105078.4; = p.R425del on NM_004991.4) | In Frame Del (DEL) | VAF 23/105 reads (22%) | catalogued as rs1226668746; called by pindel, varscan2
- MED24 | c.2680C>T p.R894W | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs142219986; called by muse, mutect2, varscan2
- MEPE | c.107G>A p.R36K | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT tolerated (0.82); PolyPhen benign (0.029); catalogued as COSV63074683; called by muse, mutect2, varscan2
- MFN1 | c.40G>T p.A14S | Missense Mutation (SNP) | VAF 60/220 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54942785; called by muse, mutect2, varscan2
- MGA | c.5543C>T p.P1848L (on ENST00000219905 / NM_001164273.1; = p.P1639L on NM_001080541.2) | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.118); catalogued as COSV54963958; called by muse, mutect2, varscan2
- MGAT4C | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs566418071, COSV59832100, COSV59837748; called by mutect2, varscan2
- MIA2 | c.2315del p.P772Hfs*15 | Frame Shift Del (DEL) | VAF 32/122 reads (26%) | catalogued as COSV54490213, COSV99697265; called by mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 18/43 reads (42%) | catalogued as rs762448666; called by pindel, varscan2
- MIEF2 | c.736G>A p.G246R | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs776955546, COSV100544168; called by muse, mutect2
- MMP27 | c.414G>A p.W138* | Nonsense Mutation (SNP) | VAF 23/99 reads (23%) | catalogued as COSV52781623; called by muse, mutect2, varscan2
- MOB3A | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1316038193, COSV63865981; called by muse, mutect2, varscan2
- MOCS3 | c.653A>G p.D218G | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV54868099; called by muse, mutect2, varscan2
- MORN1 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV66003763; called by muse, mutect2, varscan2
- MRGPRX1 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 34/223 reads (15%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.506); catalogued as rs767184906, COSV57106940; called by muse, mutect2, varscan2
- MRGPRX3 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs1333694714, COSV66934857; called by muse, mutect2, varscan2
- MRPL32 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV56238709; called by muse, mutect2, varscan2
- MRPS24 | c.257C>T p.T86M | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as rs778186629, COSV58183200; called by muse, mutect2, varscan2
- MRPS7 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.524); catalogued as COSV55454481; called by muse, mutect2, varscan2
- MSI1 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99981759; called by muse, mutect2, varscan2
- MST1 | c.1855G>A p.A619T | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.274); catalogued as COSV56537048; called by muse, mutect2, varscan2
- MTG1 | c.748T>G p.F250V | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV100448979; called by mutect2, varscan2
- MTG2 | c.1055C>A p.A352D | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV100895211; called by muse, mutect2, varscan2
- MTUS2 | c.1082G>A p.G361D | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs1347448831, COSV70923411; called by muse, mutect2, varscan2
- MUC5AC | c.969del p.L324Cfs*137 | Frame Shift Del (DEL) | VAF 9/36 reads (25%) | catalogued as rs1227165697; called by mutect2, pindel, varscan2
- MVD | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.342); catalogued as rs780694192, COSV55369392; called by muse, mutect2, varscan2
- MYBL2 | c.1799C>T p.S600F | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.708); catalogued as COSV99406842; called by muse, mutect2, varscan2
- MYCBP2 | c.8407C>T p.R2803C (on ENST00000357337; = p.R2841C on NM_015057.5) | Missense Mutation (SNP) | VAF 53/181 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.451); catalogued as rs778095352, COSV62040993; called by muse, mutect2, varscan2
- MYCN | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs776847158, COSV99808560, COSV99808611; called by mutect2, varscan2
- MYF5 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57355304, COSV99953423; called by muse, mutect2, varscan2
- MYH11 | c.4090C>T p.R1364C | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs769227102, COSV55549472; called by muse, mutect2, varscan2
- MYH14 | c.5260C>T p.R1754C | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs373716045; called by mutect2, varscan2
- MYH15 | c.1046A>T p.D349V | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56320749; called by muse, mutect2, varscan2
- MYO7A | c.6091C>T p.R2031W | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as rs369460086; called by muse, mutect2, varscan2
- MYOC | c.430A>G p.N144D | Missense Mutation (SNP) | VAF 50/236 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV50679959; called by muse, mutect2, varscan2
- MYOM3 | c.2489C>T p.A830V | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.714); catalogued as COSV58401594; called by muse, mutect2, varscan2
- MYPN | c.3581G>A p.R1194H | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1252035616, COSV62733850; called by muse, mutect2
- NBEAL2 | c.673T>C p.S225P | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as COSV52763174; called by muse, mutect2, varscan2
- NCAM1 | c.1481G>A p.R494H (on ENST00000316851 / NM_181351.5; = p.R484H on NM_000615.7) | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.653); catalogued as rs367640227; called by muse, mutect2, varscan2
- NCAPD2 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.424); catalogued as rs200920120; called by muse, mutect2, varscan2
- NCAPG | c.2901G>T p.Q967H | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV52272948; called by muse, mutect2, varscan2
- NCKAP5L | c.3571C>T p.R1191W | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs779317201, COSV100259357; called by muse, mutect2, varscan2
- NDN | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1192848406, COSV59358773; called by muse, mutect2, varscan2
- NDUFS1 | c.1093A>C p.T365P | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as COSV51914076; called by muse, mutect2, varscan2
- NEK3 | c.705G>T p.K235N | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.161); catalogued as COSV51619479; called by muse, mutect2, varscan2
- NEK4 | c.2488C>T p.R830C | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs56168225; called by muse, mutect2, varscan2
- NEK8 | c.1767G>C p.Q589H | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); catalogued as COSV52049034; called by muse, mutect2, varscan2
- NIBAN1 | c.1538C>T p.A513V | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.602); catalogued as rs750889582, COSV100836667; called by muse, mutect2, varscan2
- NKAPL | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV59199421; called by muse, mutect2, varscan2
- NLN | c.1346C>T p.A449V | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs780180376, COSV66765937; called by muse, mutect2, varscan2
- NOBOX | c.961del p.A321Pfs*27 | Frame Shift Del (DEL) | VAF 17/64 reads (27%) | catalogued as rs1174738024; called by mutect2, pindel, varscan2
- NOL6 | c.3278C>T p.P1093L | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs374584991; called by muse, mutect2, varscan2
- NOTCH4 | c.3155G>T p.S1052I | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV66684179; called by muse, mutect2, varscan2
- NPC1L1 | c.2212C>T p.R738* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as rs1340269959, CM1412456, COSV99213793; called by mutect2, varscan2
- NPEPL1 | c.650A>T p.D217V | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs201082731, COSV61940763; called by muse, mutect2, varscan2
- NPTN | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as COSV54740302; called by muse, mutect2, varscan2
- NPY | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs963845288, COSV54216159; called by muse, mutect2
- NRXN2 | c.4521dup p.T1508Hfs*82 | Frame Shift Ins (INS) | VAF 18/77 reads (23%) | catalogued as rs761307555; called by mutect2, varscan2
- NSDHL | c.953T>C p.I318T | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV64745419; called by muse, mutect2, varscan2
- NSF | c.1598G>A p.R533H | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1420619832, COSV56576892; called by muse, mutect2, varscan2
- NTM | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66183570; called by muse, mutect2, varscan2
- NTM | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs951593215, COSV66177489; called by muse, mutect2
- NTN5 | c.74G>A p.R25H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs139966788; called by muse, mutect2
- NTRK2 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0.271); catalogued as rs781137734, COSV52854689; called by muse, mutect2, varscan2
- NUP214 | c.4133dup p.V1379Gfs*60 | Frame Shift Ins (INS) | VAF 24/106 reads (23%) | catalogued as rs780417788; called by mutect2, varscan2
- NUP88 | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); catalogued as COSV56708156; called by muse, mutect2, varscan2
- OBSCN | c.5584G>A p.V1862M | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.903); catalogued as rs764613872, COSV52777658; called by muse, mutect2, varscan2
- OBSCN | c.9491G>A p.R3164H | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as rs758940130, COSV99486164; called by mutect2, varscan2
- OBSCN | c.14428C>T p.R4810W | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs367669699; called by muse, mutect2, varscan2
- OBSCN | c.17614C>T p.Q5872* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as COSV52834654; called by muse, mutect2, varscan2
- ODC1 | c.1346G>A p.R449H | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs763621553, COSV99301417; called by mutect2, varscan2
- OR10C1 | c.269G>A p.R90Q (on ENST00000622521; = p.R88Q on NM_013941.3) | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs140077218, COSV101010841; called by muse, mutect2, varscan2
- OR13D1 | c.461A>G p.H154R | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763717160, COSV59515142; called by muse, mutect2, varscan2
- OR1J1 | c.5G>A p.S2N | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV52239996; called by muse, mutect2, varscan2
- OR2AK2 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs896892574, COSV63561915; called by muse, mutect2, varscan2
- OR4C3 | c.329T>C p.I110T | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV60590864; called by muse, mutect2, varscan2
- OR4K1 | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 58/573 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.456); catalogued as COSV53462878; called by muse, mutect2
- OR51M1 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.366); catalogued as rs776468666, COSV60783935; called by muse, mutect2, varscan2
- OR5D16 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.73); catalogued as rs562661348, COSV65722453; called by muse, mutect2, varscan2
- OR5D18 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 50/204 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as rs201872777, COSV100450902, COSV61737031; called by muse, mutect2, varscan2
- OR5I1 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1565151589, COSV56887915; called by muse, mutect2
- OR8D4 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as rs987190991, COSV58431723; called by muse, mutect2, varscan2
- OR9A2 | c.629C>T p.T210M | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs369516935; called by mutect2, varscan2
- OSBPL6 | c.2366C>T p.A789V | Missense Mutation (SNP) | VAF 15/247 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99508874; called by muse, mutect2
- OTOGL | c.6553G>A p.G2185S (on ENST00000547103; = p.G2176S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54024538; called by muse, mutect2, varscan2
- OTUB2 | c.394G>A p.V132M | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781189899, COSV99180251; called by muse, mutect2, varscan2
- OTUB2 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.821); catalogued as COSV52574732; called by muse, mutect2, varscan2
- P4HA3 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.034); catalogued as rs374150475; called by muse, mutect2, varscan2
- PABPC1L | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs754003327, COSV53838739; called by muse, mutect2, varscan2
- PAPLN | c.811C>T p.R271W (on ENST00000554301; = p.R244W on NM_173462.4) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773031338, COSV53724591; called by muse, mutect2, varscan2
- PAPPA2 | c.4206T>A p.D1402E | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1215765900, COSV62812765; called by muse, mutect2, varscan2
- PAQR9 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1427521113, COSV61418636; called by muse, mutect2, varscan2
- PAQR9 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.792); catalogued as COSV61417685; called by muse, mutect2, varscan2
- PARD6B | c.212C>A p.P71H | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65405331; called by muse, mutect2, varscan2
- PARP14 | c.3221G>C p.G1074A | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV71734179, COSV71735649; called by muse, mutect2, varscan2
- PAX9 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs748361932, COSV64062634; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCBP2 | c.524del p.P175Rfs*4 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | catalogued as rs776329515; called by mutect2, pindel, varscan2
- PCDH10 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.65); catalogued as rs754653138, COSV52096329, COSV52102015; called by muse, mutect2, varscan2
- PCDH10 | c.1486G>A p.A496T | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52104723; called by muse, varscan2
- PCDH15 | c.4549G>A p.V1517I | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as COSV100905988; called by mutect2, varscan2
- PCDH17 | c.3214T>G p.L1072V | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.015); catalogued as COSV64971461, COSV64971783, COSV64972529; called by muse, mutect2, varscan2
- PCDH7 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62340379; called by muse, mutect2, varscan2
- PCDHGB4 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 33/200 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV54050201; called by muse, mutect2, varscan2
- PCLO | c.4901A>T p.D1634V | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV61670210; called by muse, mutect2, varscan2
- PCNT | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs375098069, COSV52448967; called by muse, mutect2, varscan2
- PCNX1 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as rs201113370, COSV53102732; called by muse, mutect2, varscan2
- PCSK5 | c.727C>T p.R243* | Nonsense Mutation (SNP) | VAF 10/50 reads (20%) | catalogued as rs745715735, COSV65083956; called by muse, mutect2, varscan2
- PDGFRB | c.1925G>A p.S642N | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); catalogued as COSV55810558; called by muse, mutect2, varscan2
- PDIA2 | c.1058del p.G353Afs*25 | Frame Shift Del (DEL) | VAF 12/49 reads (24%) | catalogued as rs746140719, COSV51993734; called by pindel, varscan2
- PDZD7 | c.301G>A p.V101M | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs754095314, COSV64647719; called by muse, mutect2, varscan2
- PDZD7 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); catalogued as COSV56521493; called by mutect2, varscan2
- PEAR1 | c.1985C>T p.A662V | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.734); catalogued as COSV52776143; called by muse, mutect2, varscan2
- PEG3 | c.142A>G p.R48G | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs1416680647, COSV55648956; called by muse, mutect2, varscan2
- PELP1 | c.1712C>T p.T571M | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.685); catalogued as rs750151202, COSV52592845; called by muse, mutect2, varscan2
- PEX11G | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as rs145286187; called by muse, mutect2, varscan2
- PGAP4 | c.1127G>T p.R376M | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); catalogued as COSV66388492; called by muse, mutect2
- PGBD1 | c.2005del p.M669* | Frame Shift Del (DEL) | VAF 24/133 reads (18%) | catalogued as rs781166611; called by mutect2, varscan2
- PGBD5 | c.1277C>T p.A426V (on ENST00000525115; = p.A495V on NM_001258311.2) | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.994); catalogued as COSV58413949; called by muse, mutect2, varscan2
- PGK2 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs759933654, COSV100505678, COSV59165764; called by muse, mutect2, varscan2
- PHETA1 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754897992, COSV64059708; called by muse, mutect2, varscan2
- PHF13 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as rs138938066; called by muse, mutect2, varscan2
- PHF14 | c.271T>C p.S91P | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.021); catalogued as COSV68857539; called by muse, varscan2
- PHF2 | c.1559C>T p.T520M | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs373926607; called by muse, mutect2, varscan2
- PID1 | c.415C>T p.R139W (on ENST00000354069 / NM_001330156.1; = p.R137W on NM_017933.5) | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs756817470, COSV62475830; called by muse, mutect2, varscan2
- PIGB | c.529dup p.C177Lfs*79 | Frame Shift Ins (INS) | VAF 36/173 reads (21%) | catalogued as rs1356026422; called by mutect2, varscan2
- PIGK | c.633G>A p.M211I | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV63063750; called by muse, mutect2, varscan2
- PIGR | c.1509C>A p.C503* | Nonsense Mutation (SNP) | VAF 9/56 reads (16%) | catalogued as COSV62905170; called by muse, mutect2, varscan2
- PINK1 | c.1697C>T p.T566M | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.276); catalogued as rs777903263, COSV58633106; called by muse, mutect2, varscan2
- PIWIL1 | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.885); catalogued as rs201447253; called by muse, mutect2, varscan2
- PKD2 | c.1844C>T p.A615V | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as COSV52941526; called by muse, mutect2, varscan2
- PKM | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs772455998, COSV58788820; called by muse, mutect2, varscan2
- PLA2G4F | c.2510C>A p.A837D | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV51829706; called by muse, mutect2, varscan2
- PLAT | c.943C>T p.L315F | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.776); catalogued as COSV54278394; called by muse, mutect2, varscan2
- PLCE1 | c.6628C>T p.R2210W | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1363480647, COSV53373943; called by muse, mutect2, varscan2
- PLCG1 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54824512; called by muse, mutect2, varscan2
- PLCG2 | c.2779G>A p.A927T | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV63870557; called by muse, mutect2, varscan2
- PLEKHG1 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62047633; called by muse, mutect2, varscan2
- PLEKHH2 | c.3096G>T p.Q1032H | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as COSV99175333; called by muse, mutect2, varscan2
- PLIN4 | c.1144G>C p.V382L (on ENST00000301286; = p.V397L on NM_001367868.2) | Missense Mutation (SNP) | VAF 31/161 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56699472; called by muse, mutect2, varscan2
- PLXNA4 | c.2944G>A p.G982R | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58135892; called by muse, mutect2, varscan2
- PNOC | c.269C>T p.S90L | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.371); catalogued as rs764588634, COSV100108409; called by muse, mutect2, varscan2
- PNPLA2 | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.206); catalogued as rs988744471, COSV100352044, COSV60745415; ClinVar: uncertain significance; called by muse, mutect2
- POLM | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV54244130; called by muse, mutect2, varscan2
- POLR1G | c.1283_1286del p.K428Rfs*6 | Frame Shift Del (DEL) | VAF 7/44 reads (16%) | catalogued as rs778473284; called by pindel, varscan2
- POLR2A | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763272826, COSV59492062, COSV59495240; called by mutect2, varscan2
- POMGNT1 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 16/107 reads (15%) | PolyPhen benign (0.201); catalogued as rs756234628, COSV64339578; called by muse, mutect2, varscan2
- PON1 | c.746A>G p.E249G | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV99732694; called by muse, mutect2, varscan2
- POTEE | c.127G>A p.V43M | Missense Mutation (SNP) | VAF 82/299 reads (27%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.009); catalogued as rs760098912, COSV58245823; called by mutect2, varscan2
- PPFIA4 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756691763, COSV99830673; called by muse, mutect2, varscan2
- PPFIBP1 | c.1025C>T p.T342M (on ENST00000318304 / NM_177444.3; = p.T322M on NM_003622.4) | Missense Mutation (SNP) | VAF 51/274 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs142893025; called by muse, mutect2, varscan2
- PPIL4 | c.563G>T p.S188I | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as COSV53568983; called by muse, mutect2, varscan2
- PPP1R12A | c.1619del p.N540Ifs*23 | Frame Shift Del (DEL) | VAF 19/62 reads (31%) | catalogued as rs776166170; called by mutect2, varscan2
- PPP1R15B | c.531G>T p.E177D | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); catalogued as COSV65816632; called by muse, mutect2, varscan2
- PPP1R2 | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.93); PolyPhen benign (0.005); catalogued as rs751525820, COSV60497702; called by muse, mutect2, varscan2
- PPP6R2 | c.438G>T p.K146N | Missense Mutation (SNP) | VAF 49/184 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53299076; called by muse, mutect2, varscan2
- PRAME | c.1504C>A p.L502M | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.204); catalogued as COSV67161005, COSV67162540; called by muse, mutect2, varscan2
- PRAMEF1 | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 67/303 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as rs756544879, COSV60019315; called by muse, mutect2, varscan2
- PRAMEF17 | c.1027C>A p.L343M | Missense Mutation (SNP) | VAF 87/412 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101068815; called by muse, mutect2, varscan2
- PRG4 | c.3031G>T p.A1011S | Missense Mutation (SNP) | VAF 41/164 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as COSV63356566; called by muse, mutect2, varscan2
- PRKCD | c.1300del p.D434Tfs*2 | Frame Shift Del (DEL) | VAF 14/47 reads (30%) | catalogued as rs1559629912, COSV57847601; called by mutect2, pindel, varscan2
- PRKCQ | c.235G>A p.V79M | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs148376969, COSV54117893; called by muse, mutect2, varscan2
- PRPF40A | c.2483G>A p.R828Q | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.361); catalogued as COSV68359595; called by muse, mutect2, varscan2
- PRPS2 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.565); catalogued as rs762554014, COSV66126056, COSV66126686; called by muse, mutect2, varscan2
- PRPS2 | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.994); catalogued as COSV66180337; called by muse, mutect2, varscan2
- PRRT1 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52999746; called by muse, mutect2, varscan2
- PSD2 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV51213237; called by muse, mutect2, varscan2
- PTCH1 | c.290dup p.N97Kfs*43 | Frame Shift Ins (INS) | VAF 22/70 reads (31%) | catalogued as COSV59501459; called by mutect2, varscan2
- PTCHD3 | c.2057dup p.N686Kfs*6 | Frame Shift Ins (INS) | VAF 12/72 reads (17%) | catalogued as rs750923568; called by mutect2, varscan2
- PTGDR | c.799C>A p.L267M | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60094321, COSV60095219; called by muse, mutect2, varscan2
- PTPN13 | c.356G>T p.S119I | Missense Mutation (SNP) | VAF 36/330 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV57418354; called by muse, mutect2, varscan2
- PTPN23 | c.4726T>C p.S1576P | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV55548762; called by muse, mutect2, varscan2
- PTPRB | c.4346del p.P1449Lfs*9 | Frame Shift Del (DEL) | VAF 14/55 reads (25%) | catalogued as rs1476690081; called by mutect2, pindel, varscan2
- PTPRD | c.5673T>C p.D1891= | Splice Region (SNP) | VAF 10/85 reads (12%) | catalogued as COSV61984641; called by muse, mutect2, varscan2
- PTPRN2 | c.2111G>T p.S704I | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV67060971; called by muse, mutect2, varscan2
- PTPRS | c.4028G>A p.R1343H | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201934952, COSV53639166; called by muse, mutect2, varscan2
- PTPRU | c.3788G>A p.R1263Q | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760809964, COSV60537283; called by muse, mutect2, varscan2
- PTPRZ1 | c.1531G>A p.A511T | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.026); catalogued as rs962400214, COSV66446283; called by muse, mutect2, varscan2
- PTPRZ1 | c.4779C>A p.F1593L | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV66446290; called by muse, mutect2, varscan2
- PUM1 | c.2975C>T p.A992V | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV57085701; called by muse, mutect2, varscan2
- PUM2 | c.601G>A p.G201R | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.081); catalogued as rs778700744, COSV57585700; called by muse, mutect2, varscan2
- RAB43 | c.187C>T p.Q63* | Nonsense Mutation (SNP) | VAF 10/106 reads (9%) | catalogued as COSV59349931; called by muse, mutect2
- RALA | c.197T>A p.I66N | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99143541; called by muse, mutect2
- RALGDS | c.2318G>A p.R773H | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as rs561121466, COSV64429818; called by muse, mutect2, varscan2
- RALGDS | c.1487G>A p.R496H | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs550664081, COSV64426981, COSV64429833; called by muse, mutect2, varscan2
- RAPGEF5 | c.647del p.K216Rfs*22 (on ENST00000401957 / NM_001367602.2; = p.K519Rfs*22 on NM_012294.5) | Frame Shift Del (DEL) | VAF 24/140 reads (17%) | catalogued as rs770990761; called by mutect2, pindel, varscan2
- RASL10B | c.209C>T p.T70M | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as rs1403129089; called by muse, mutect2
- RBM12 | c.709C>A p.P237T | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100467851, COSV100468279; called by mutect2, varscan2
- RBM38 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV61135345; called by muse, mutect2, varscan2
- RBMX2 | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); catalogued as COSV59728375; called by muse, mutect2, varscan2
- RBPMS | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.973); catalogued as rs1449308525, COSV55122870; called by muse, mutect2
- RCAN2 | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 40/267 reads (15%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.994); catalogued as rs770255594, COSV100149047, COSV57819878; called by muse, mutect2, varscan2
- RCC2 | c.956C>T p.T319M | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.938); catalogued as rs1034037689, COSV64906295; called by muse, mutect2, varscan2
- RCN1 | c.886A>G p.K296E | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.212); catalogued as COSV50015316; called by muse, mutect2, varscan2
- RCSD1 | c.1058C>T p.P353L | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as COSV63261278; called by muse, mutect2, varscan2
- RECK | c.1526G>A p.R509Q | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs750000887, COSV65035715; called by muse, mutect2, varscan2
- RELA | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs969818412, COSV100425986; called by muse, mutect2, varscan2
- RELN | c.8864G>A p.R2955H | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as COSV59036044; called by muse, mutect2, varscan2
- RESF1 | c.3761A>T p.D1254V | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.191); catalogued as COSV100440717; called by muse, mutect2, varscan2
- RFTN2 | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 21/162 reads (13%) | catalogued as COSV54393528; called by muse, mutect2, varscan2
- RGS11 | c.902G>A p.G301D (on ENST00000397770 / NM_183337.3; = p.G280D on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); catalogued as COSV51454230; called by muse, mutect2, varscan2
- RGS22 | c.827A>G p.E276G | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as COSV62668230; called by muse, mutect2, varscan2
- RHAG | c.680C>T p.S227L | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs902283342, COSV57706635; called by muse, mutect2, varscan2
- RHOXF1 | c.442C>T p.R148W | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV54294218; called by muse, mutect2, varscan2
- RIMS1 | c.54del p.M19Cfs*7 | Frame Shift Del (DEL) | VAF 13/75 reads (17%) | catalogued as rs1378143186; called by mutect2, pindel, varscan2
- RIMS1 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV53442893; called by muse, mutect2, varscan2
- RIMS1 | c.4592G>A p.R1531H | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs759999855, COSV53449648, COSV53465710; called by muse, mutect2, varscan2
- RNF151 | c.637C>A p.L213M | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV58401096; called by muse, mutect2, varscan2
- RNF180 | c.661A>G p.T221A | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs776775433, COSV56965531; called by muse, mutect2, varscan2
- RNF213 | c.2238_2239del p.K747Afs*16 | Frame Shift Del (DEL) | VAF 29/160 reads (18%) | catalogued as rs1330689183; called by pindel, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 24/114 reads (21%) | catalogued as rs755128667, COSV68457540; called by pindel, varscan2
- ROBO4 | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.869); catalogued as rs755801141, COSV60621702; called by mutect2, varscan2
- RP1 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.939); catalogued as COSV55110815; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPS6 | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as rs1283528998, COSV59547449; called by muse, mutect2
- RPS6KA4 | c.1585C>T p.R529C | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV53707183; called by muse, mutect2
- RRNAD1 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs933601524, COSV57461405; called by muse, mutect2, varscan2
- RSPH6A | c.782A>G p.D261G | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs1342719494, COSV55575816; called by muse, mutect2, varscan2
- RTCB | c.1502C>T p.A501V | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); catalogued as COSV53280712; called by muse, mutect2, varscan2
- RYR2 | c.6083G>A p.R2028H | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.793); catalogued as rs1313042151, COSV63661968; called by muse, mutect2, varscan2
- S1PR1 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59512423; called by muse, mutect2, varscan2
- S1PR5 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0.074); catalogued as COSV100330829; called by muse, mutect2, varscan2
- SAC3D1 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV57248731; called by muse, mutect2, varscan2
- SAFB | c.20G>T p.G7V | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV52654291; called by muse, mutect2, varscan2
- SAMD4A | c.1085C>T p.A362V | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV51878926, COSV99200823; called by muse, mutect2, varscan2
- SASS6 | c.567dup p.Q190Tfs*5 | Frame Shift Ins (INS) | VAF 43/203 reads (21%) | catalogued as rs778258887; called by mutect2, varscan2
- SATB2 | c.1358G>A p.S453N | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV53493220; called by muse, mutect2, varscan2
- SBF1 | c.3228del p.S1077Afs*28 | Frame Shift Del (DEL) | VAF 15/68 reads (22%) | catalogued as rs771002611; called by mutect2, pindel, varscan2
- SBNO1 | c.3416del p.N1139Mfs*9 (on ENST00000420886; = p.N1138Mfs*9 on NM_018183.5) | Frame Shift Del (DEL) | VAF 24/96 reads (25%) | catalogued as rs765867975; called by mutect2, varscan2
- SBNO2 | c.1880G>A p.R627Q | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs765584534, COSV62324017; called by muse, mutect2, varscan2
- SCAF4 | c.211C>T p.R71* | Nonsense Mutation (SNP) | VAF 14/105 reads (13%) | catalogued as rs1439594249, COSV54584476, COSV54585696; called by muse, mutect2, varscan2
- SCFD1 | c.1723C>T p.R575W | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs753170714, COSV61722253; called by muse, mutect2, varscan2
- SCN3A | c.1858C>T p.R620* | Nonsense Mutation (SNP) | VAF 14/144 reads (10%) | catalogued as rs1288869563, COSV51800546, COSV51814482; called by muse, mutect2, varscan2
- SCNM1 | c.551C>A p.P184H | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54862127; called by muse, mutect2, varscan2
- SDS | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57454705; called by muse, mutect2, varscan2
- SEC31A | c.1541C>T p.A514V | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV52352373; called by muse, mutect2, varscan2
- SECISBP2L | c.1413del p.K471Nfs*20 (on ENST00000559471 / NM_001193489.2; = p.K426Nfs*20 on NM_014701.4) | Frame Shift Del (DEL) | VAF 15/73 reads (21%) | catalogued as rs768725524; called by mutect2, varscan2
- SELENOM | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.608); catalogued as rs1211131930, COSV100295052; called by muse, mutect2, varscan2
- SEMA3D | c.686G>A p.R229K | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.254); catalogued as COSV52393288, COSV99407613; called by muse, mutect2, varscan2
- SERPINB12 | c.449del p.N150Tfs*39 | Frame Shift Del (DEL) | VAF 21/98 reads (21%) | catalogued as rs760486497; called by mutect2, pindel, varscan2
- SERPINE3 | c.808del p.L270* | Frame Shift Del (DEL) | VAF 9/43 reads (21%) | catalogued as rs753981280; called by mutect2, pindel, varscan2
- SESTD1 | c.1697G>A p.C566Y | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.974); catalogued as COSV58933001; called by muse, mutect2, varscan2
- SETBP1 | c.2740C>T p.R914W | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs758128091, COSV56337985, COSV99954730; called by muse, mutect2, varscan2
- SETD1A | c.1178del p.P393Lfs*104 | Frame Shift Del (DEL) | VAF 23/123 reads (19%) | catalogued as COSV52689654; called by mutect2, pindel, varscan2
- SETDB1 | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54992937; called by muse, mutect2, varscan2
- SFRP2 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.028); catalogued as rs778665160, COSV56836634; called by muse, mutect2, varscan2
- SFRP4 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs555863176, COSV52259818; called by muse, mutect2, varscan2
- SFSWAP | c.241C>T p.H81Y | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.316); catalogued as COSV55526270; called by muse, mutect2, varscan2
- SH3TC1 | c.2525C>T p.P842L | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs755369951, COSV55290349; called by muse, mutect2, varscan2
- SHANK2 | c.2803G>A p.A935T | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.176); catalogued as rs199629765, COSV53588648; called by muse, mutect2, varscan2
- SHCBP1L | c.1017del p.K339Nfs*5 | Frame Shift Del (DEL) | VAF 29/126 reads (23%) | catalogued as rs756742767; called by mutect2, pindel, varscan2
- SIGLEC9 | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.311); catalogued as COSV51583045; called by muse, mutect2, varscan2
- SIPA1L1 | c.1942C>T p.R648* | Nonsense Mutation (SNP) | VAF 19/133 reads (14%) | catalogued as rs1432910352, COSV100666081, COSV62170051, COSV62173814; called by muse, mutect2, varscan2
- SIPA1L3 | c.2297C>A p.A766D | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV55925067; called by muse, mutect2, varscan2
- SIPA1L3 | c.3260C>A p.P1087H | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as COSV55925083; called by muse, mutect2, varscan2
- SIRPA | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 50/198 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.102); catalogued as rs776144552, COSV61541742; called by muse, mutect2, varscan2
- SLAIN1 | c.1553G>A p.R518H (on ENST00000466548; = p.R255H on NM_144595.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs764341266, COSV57385488, COSV57389537; called by muse, mutect2, varscan2
- SLAIN2 | c.1613G>T p.R538I | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51910899; called by muse, mutect2, varscan2
- SLC12A1 | c.1563T>G p.A521= | Splice Region (SNP) | VAF 43/120 reads (36%) | catalogued as COSV66800245; called by muse, mutect2, varscan2
- SLC12A5 | c.2661G>A p.M887I (on ENST00000454036 / NM_001134771.2; = p.M864I on NM_020708.5) | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV54802660; called by muse, mutect2, varscan2
- SLC16A12 | c.219del p.F73Lfs*22 | Frame Shift Del (DEL) | VAF 14/51 reads (27%) | catalogued as rs760181506; called by mutect2, varscan2
- SLC16A6 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs1194564209, COSV100517452; called by muse, mutect2
- SLC17A3 | c.113G>T p.R38L | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs139869471, COSV57759461, COSV57761661; called by muse, mutect2, varscan2
- SLC19A1 | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.387); catalogued as rs772342183, COSV60752832; called by muse, mutect2, varscan2
- SLC20A2 | c.1435G>T p.D479Y | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60607375; called by mutect2, varscan2
- SLC23A1 | c.565A>G p.T189A | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (1); PolyPhen possibly damaging (0.82); catalogued as COSV100812137; called by muse, mutect2, varscan2
- SLC24A1 | c.2381G>T p.C794F | Missense Mutation (SNP) | VAF 71/343 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV56054347; called by muse, mutect2, varscan2
- SLC24A2 | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99647669; called by muse, mutect2, varscan2
- SLC25A24 | c.570del p.K190Nfs*29 | Frame Shift Del (DEL) | VAF 24/104 reads (23%) | catalogued as rs763273320; called by mutect2, varscan2
- SLC25A3 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.03); catalogued as rs1368158297, COSV51848157; called by muse, mutect2, varscan2
- SLC27A5 | c.922A>G p.T308A | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as COSV54020168; called by muse, mutect2, varscan2
- SLC35G6 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV59493453; called by muse, mutect2, varscan2
- SLC45A3 | c.598T>G p.F200V | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65655617; called by muse, mutect2, varscan2
- SLC46A1 | c.560G>T p.S187I | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.075); catalogued as COSV58708959; called by muse, mutect2, varscan2
- SLC4A1 | c.548A>G p.D183G | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV99293786; called by muse, mutect2
- SLC5A2 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs760532652, COSV57894019; called by muse, varscan2
- SLC5A3 | c.1589G>A p.S530N | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62969086, COSV62973826; called by muse, mutect2, varscan2
- SLC6A11 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54399486; called by muse, mutect2, varscan2
- SLC8A2 | c.2189C>T p.T730M | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs750760536, COSV52641567; called by muse, mutect2, varscan2
- SLCO4C1 | c.1724C>T p.A575V | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs144643168; called by muse, mutect2, varscan2
- SLCO6A1 | c.154A>G p.R52G | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1222547905, COSV101135187; called by muse, mutect2, varscan2
- SLFN12 | c.555del p.F185Lfs*12 | Frame Shift Del (DEL) | VAF 22/74 reads (30%) | catalogued as rs747319777; called by mutect2, varscan2
- SLIT1 | c.3835C>A p.L1279I | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.735); catalogued as COSV56596926, COSV56599983; called by muse, mutect2, varscan2
- SLITRK2 | c.181dup p.Q61Pfs*35 | Frame Shift Ins (INS) | VAF 25/69 reads (36%) | catalogued as rs781792891; called by mutect2, varscan2
- SLITRK5 | c.1556C>T p.A519V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as COSV100281345; called by muse, mutect2
- SLX4IP | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.112); catalogued as rs758437771, COSV57946485; called by mutect2, varscan2
- SMARCAD1 | c.1040del p.N347Mfs*24 | Frame Shift Del (DEL) | VAF 44/89 reads (49%) | catalogued as rs754697669; called by mutect2, varscan2
- SMARCC2 | c.1424T>C p.L475P | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57225492; called by muse, mutect2
- SMG5 | c.2983G>A p.A995T | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.352); catalogued as rs769289830, COSV52746811; called by muse, mutect2, varscan2
- SMG7 | c.2545del p.M849* | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | catalogued as rs749889899; called by mutect2, varscan2
- SMIM19 | c.259+2T>C p.X87_splice | Splice Site (SNP) | VAF 13/48 reads (27%) | catalogued as COSV69327091; called by muse, mutect2, varscan2
- SMTN | c.714del p.S239Afs*118 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | catalogued as rs747405143; called by mutect2, pindel, varscan2
- SNIP1 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as COSV99953315; called by muse, mutect2, varscan2
- SOX11 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1221789039, COSV100431556, COSV58988161; called by muse, mutect2, varscan2
- SP110 | c.1013C>T p.A338V | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.265); catalogued as COSV51276434; called by muse, mutect2, varscan2
- SP6 | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs1054037612, COSV60619210; called by muse, mutect2, varscan2
701 further variants in this file (337 protein-altering or splice-affecting, 343 silent, 21 other) are not listed here.
